CPTAC case C3L-09379 — Stomach — Adenomas and Adenocarcinomas (CPTAC-3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of the Clinical Proteomic Tumor Analysis Consortium (CPTAC). Disease type: Adenomas and Adenocarcinomas; Primary site: Stomach. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/17b628fa-e1e4-4055-9d27-a41e109c8ce2

Demographics
Sex at birth: male; Race: white; Year of birth: 1958; Vital status: Alive; Country of birth: Serbia.

Diagnoses (1)
1. Adenocarcinoma, NOS: ICD-O-3 morphology code: 8140/3; Tissue or organ of origin: Stomach, NOS; Site of resection or biopsy: Stomach, NOS; Age at diagnosis: 64.2 years (23,463 days); Year of diagnosis: 2022; AJCC staging edition: 8th; AJCC pathologic T: T2; AJCC pathologic N: N3a; AJCC pathologic stage: Stage IIA; Tumor grade: G2; Residual disease: R0; Days to last known disease status: 1,085 days (3.0 years); Progression or recurrence: no; Days to last follow up: 1,085 days (3.0 years); Tumor focality: Unifocal.
   Pathology details: Greatest tumor dimension: 4.7 cm; Lymph node involvement: Positive; Lymph nodes positive: 14; Lymph nodes tested: 21.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Capecitabine + Paclitaxel; Days to treatment start: 65 days; Days to treatment end: 190 days; Treatment outcome: Complete Response.

Follow-up (2 entries)
- Days to follow up: 399 days (1.1 years); Disease response: Complete Response; Karnofsky performance status: 90; ECOG performance status: 1.
- Days to follow up: 783 days (2.1 years); Disease response: Complete Response; Karnofsky performance status: 90; ECOG performance status: 1.

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample C3L-09379-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Stomach; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: 36 days; Initial weight: 161 mg; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide C3L-09379-22: Section location: Stomach, NOS; Percent tumor nuclei: 75; Percent necrosis: 5.
- Sample C3L-09379-31: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood Components NOS; Biospecimen anatomic site: Blood; Preservation method: Frozen; Freezing method: -20 (unit not recorded by GDC); Days to sample procurement: 37 days; Method of sample procurement: Blood Draw.
